Gene-level copy-number profile of tumor specimen TCGA-34-5241-01A from TCGA case TCGA-34-5241, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 79.7 years (29,098 days).
Specimen TCGA-34-5241-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.3def2b55-c1b1-4b07-abf3-72574c47e17f.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-34-5241-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 353 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f8197f6c-0864-45f1-8b9e-de261bde5388

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 3: 2,907; copy number 4: 3,757; copy number 5: 40,931; copy number 6: 9,099; copy number 7: 2,229; copy number 8: 717; copy number 9: 203; copy number 10: 135; copy number 11: 6; copy number 12: 55; copy number 15: 31; copy number 16: 3; copy number 17: 150; copy number 25: 8; copy number 26: 39.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-34-5241-01A-01D-1439-01): tumor purity 0.88, ploidy 3.75, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 292 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:112,995,517–114,420,302, 46 genes, copy number 12: POLR2DP1, IL36A, IL36B, IL36RN, IL1F10, RNU6-1180P, IL1RN, PSD4, AC016683.1, PAX8-AS1, PAX8, AC016745.1, IGKV1OR2-108, AC016745.2, CBWD2, FOXD4L1, LINC01961, PGM5P4-AS1, PGM5P4, FAM138B, AL078621.2, MIR1302-3, WASH2P, DDX11L2, AL078621.1, RPL23AP7, RABL2A, SNRPA1P1, ACRP1, AC017074.2, AC017074.1, RNU6-744P, SLC35F5, MIR4782, AC104653.2, AC104653.1, AC110769.2, ACTR3, AC110769.3, LINC01191, AC110769.1, U3, AC010982.2, AC010982.1, SEPHS1P7, RNU2-41P.
- chr3:186,105,668–186,570,543, 6 genes, copy number 11: DGKG, LINC02020, LINC02052, LINC02051, CRYGS, TBCCD1.
- chr3:186,789,880–187,078,553, 9 genes, copy number 12 (within-gene range 6–12): RFC4, AC112907.1, LINC02043, AC112907.2, ADIPOQ, ADIPOQ-AS1, RPS20P14, AC007690.1, ST6GAL1.
- chr12:37,575,587–38,087,392, 3 genes, copy number 16: ZNF970P, AK6P2, CLUHP8.
- chr12:40,393,395–40,570,832, 1 gene, copy number 15 (within-gene range 8–15): MUC19.
- chr12:40,554,161–43,054,386, 38 genes, copy number 15–25: RNU6-713P, CNTN1, AC016144.1, AC015540.1, PDZRN4, AC090531.1, RNA5SP360, MTND2P17, MTND1P24, LINC02400, AC090630.1, AC006197.1, AC006197.2, AC023513.1, GXYLT1, YAF2, PPHLN1, AC020629.1, ZCRB1, MIR7851, SNORA74, AC079684.1, RNU6-249P, AC079601.2, Y_RNA, PRICKLE1, AC079601.1, AC079600.3, LINC02402, AC079600.2, AC079600.1, LINC02451, RPS27P21, LINC02450, AC068802.1, AC012038.2, AC012038.1, MRPS36P5.
- chr12:45,215,987–45,440,404, 1 gene, copy number 26 (within-gene range 5–26): ANO6.
- chr12:45,444,766–47,485,722, 38 genes, copy number 26: AC063924.1, AC079950.1, U6, AC008124.1, ARID2, AC009464.1, RN7SL246P, KNOP1P2, SCAF11, AC084878.1, SLC38A1, AC025031.3, SLC38A2, AC025031.2, AC008014.1, AC025031.1, AC025031.4, AC025031.5, AC008035.1, OR7A19P, MARK3P1, SLC38A4, AC079906.1, AMIGO2, PCED1B, IFITM3P6, MIR4698, PCED1B-AS1, AC008083.2, AC008083.3, AC008083.4, PPIAP45, AC008083.1, LINC02416, MIR4494, LINC02156, ADI1P3, AC003686.1.
- chr12:64,920,845–64,982,524, 1 gene, copy number 17 (within-gene range 5–17): LINC02231.
- chr12:65,017,468–72,728,844, 149 genes, copy number 17 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
